Somatic mutation profile of tumor specimen TCGA-53-7813-01A (aliquot TCGA-53-7813-01A-11D-2167-08) from TCGA case TCGA-53-7813, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 51.7 years (18,875 days).
Specimen TCGA-53-7813-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5e85aa5-64db-4a3e-9419-aad9bba12488.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-53-7813-10A (Blood Derived Normal), aliquot TCGA-53-7813-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f09a0f5c-d15f-40c1-b60a-586f4b4f7701

The open-access MAF lists 165 somatic variants for this specimen: 132 protein-altering or splice-affecting, 27 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 27, Nonsense Mutation 12, Splice Site 6, Frame Shift Del 5, Frame Shift Ins 3, RNA 2, 5'Flank 2, Intron 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 7/44 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MC2R | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs104894661, CM960958, COSV59620540; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.179dup p.Y60* | Nonsense Mutation (INS) | VAF 16/44 reads (36%) | catalogued as rs876661012, CI055775, COSV100479367; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AC100868.1 | c.962A>T p.E321V | Missense Mutation (SNP) | VAF 104/209 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51850190; called by muse, mutect2, varscan2
- ADAMTS9 | c.3936G>C p.E1312D | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV55780460, COSV55791048; called by muse, mutect2, varscan2
- ADAR | c.2879A>G p.Y960C | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM042283, COSV52721401; called by muse, mutect2, varscan2
- AKR1B10 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV62056652; called by muse, mutect2, varscan2
- AP1S1 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV61760928, COSV61760936; called by muse, mutect2, varscan2
- ARHGAP28 | c.1120+1G>T p.X374_splice (on ENST00000383472 / NM_001366230.1; = p.X215_splice on NM_001010000.3) | Splice Site (SNP) | VAF 9/69 reads (13%) | catalogued as COSV51646550; called by muse, mutect2, varscan2
- ARMC5 | c.1318C>G p.P440A | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs535294233, COSV51660119; called by muse, mutect2
- ATG16L1 | c.666A>T p.K222N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV61468181; called by muse, mutect2, varscan2
- ATM | c.4460C>A p.S1487* | Nonsense Mutation (SNP) | VAF 51/170 reads (30%) | catalogued as COSV53776113; called by muse, mutect2, varscan2
- ATP7A | c.4025T>G p.V1342G | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58454284; called by muse, mutect2
- AVPR2 | c.938T>A p.L313Q | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61686997; called by muse, mutect2, varscan2
- BAZ2B | c.3653T>A p.I1218N | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV54276915; called by muse, mutect2, varscan2
- C2CD2L | c.1490-2A>G p.X497_splice | Splice Site (SNP) | VAF 22/94 reads (23%) | catalogued as COSV100370996; called by muse, mutect2
- C2CD2L | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100370997; called by muse, mutect2
- C2CD5 | c.1829A>T p.H610L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV61727865; called by muse, mutect2, varscan2
- CABYR | c.1435C>A p.L479I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.355); catalogued as COSV59112882; called by muse, mutect2, varscan2
- CARD11 | c.658A>T p.M220L | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV62720155; called by muse, mutect2, varscan2
- CAV2 | c.370A>T p.M124L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as COSV56064646; called by muse, mutect2, varscan2
- CDH8 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs1178029741, COSV100183866, COSV54901521; called by mutect2, varscan2
- CFAP161 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV54430528; called by muse, mutect2, varscan2
- CLCA4 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1260215673, COSV55371311; called by muse, mutect2, varscan2
- CLHC1 | c.1565-2A>C p.X522_splice | Splice Site (SNP) | VAF 18/44 reads (41%) | catalogued as COSV101284809; called by muse, mutect2, varscan2
- CNTF | c.407G>C p.R136P | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60161033, COSV60162162; called by muse, varscan2
- COIL | c.572G>A p.C191Y | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs770040861, COSV53596678; called by muse, mutect2, varscan2
- COL28A1 | c.1792-2A>G p.X598_splice | Splice Site (SNP) | VAF 26/70 reads (37%) | catalogued as rs766032169, COSV68084884; called by muse, mutect2, varscan2
- CPT1C | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV54922350; called by muse, mutect2, varscan2
- CSMD3 | c.10990G>T p.G3664* (on ENST00000297405 / NM_001363185.1; = p.G3495* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 16/264 reads (6%) | catalogued as COSV52194223; called by muse, mutect2
- CSMD3 | c.4730G>T p.W1577L (on ENST00000297405 / NM_001363185.1; = p.W1473L on NM_052900.3) | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99820805; called by muse, mutect2
- CSNK1D | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.081); catalogued as COSV53927457; called by muse, mutect2, varscan2
- CSTF1 | c.170-1G>T p.X57_splice | Splice Site (SNP) | VAF 20/67 reads (30%) | catalogued as COSV53860590; called by muse, mutect2, varscan2
- CUBN | c.3558C>A p.Y1186* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV64727646; called by muse, mutect2, varscan2
- DCAF4L2 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60479394, COSV60480003; called by muse, mutect2
- DOC2A | c.463G>C p.V155L | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV58752895; called by muse, mutect2, varscan2
- DPH5 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59859601, COSV59860479; called by muse, mutect2, varscan2
- DTD1 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs370279612, COSV101079585; called by muse, mutect2, varscan2
- DUSP21 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs1469665033, COSV59134941; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.854G>T p.S285I | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.882); catalogued as COSV62571073; called by muse, mutect2, varscan2
- EPN2 | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59063590; called by muse, mutect2
- ERN2 | c.466C>A p.R156S | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs143761786, COSV56838101; called by muse, mutect2, varscan2
- FAT4 | c.11153G>T p.R3718L | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV58709692; called by muse, mutect2, varscan2
- FITM2 | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV67679225; called by muse, mutect2, varscan2
- FMR1 | c.1667A>T p.H556L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.03); catalogued as COSV54427635; called by muse, mutect2, varscan2
- FOXO4 | c.563del p.G188Afs*87 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as COSV58575184; called by mutect2, varscan2
- FYN | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs764943142, COSV57616925; called by muse, mutect2, varscan2
- G6PC2 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs752588930, COSV56371893; called by muse, mutect2, varscan2
- GATA1 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1557020556, COSV64963548; called by muse, mutect2, varscan2
- GINM1 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV66390343; called by muse, mutect2, varscan2
- GPR45 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1289396618, COSV51524828; called by muse, mutect2, varscan2
- GPRASP1 | c.3388A>G p.R1130G | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV64356512; called by muse, mutect2
- GRM8 | c.1553T>A p.L518Q | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV58870966, COSV58872544; called by muse, mutect2, varscan2
- HMCN1 | c.13655G>A p.R4552K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV104376449, COSV54942974; called by muse, mutect2, varscan2
- HSPG2 | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65977519; called by muse, mutect2, varscan2
- INPP5E | c.1172C>G p.S391C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV65497297; called by muse, mutect2, varscan2
- INVS | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as COSV52450340; called by muse, mutect2, varscan2
- ITGAX | c.2383G>T p.V795L | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51651788; called by muse, mutect2, varscan2
- ITGB4 | c.2836G>T p.V946L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52333011; called by muse, mutect2, varscan2
- JADE3 | c.1328A>G p.N443S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782223139, COSV54470411; called by muse, mutect2, varscan2
- JAK2 | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 59/149 reads (40%) | catalogued as COSV67678408; called by muse, mutect2, varscan2
- KRT35 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs1001062970, COSV55844652; called by muse, mutect2, varscan2
- KRTAP21-2 | c.172G>T p.G58* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV61684696; called by muse, mutect2, varscan2
- LAMA2 | c.3866G>A p.R1289K | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.469); catalogued as rs199833683, COSV101369835; called by muse, mutect2, varscan2
- LAMA2 | c.3867G>T p.R1289S | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.653); catalogued as COSV101369836; called by muse, mutect2, varscan2
- LANCL2 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1419558558, COSV54652800; called by muse, mutect2, varscan2
- LRFN5 | c.1017C>A p.N339K | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV53243386, COSV53274506, COSV53276088; called by muse, mutect2, varscan2
- MAEA | c.650C>G p.A217G (on ENST00000303400 / NM_001017405.3; = p.A176G on NM_005882.5) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1176031105, COSV53264851; called by muse, mutect2, varscan2
- MAGEA11 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 54/288 reads (19%) | catalogued as COSV60756890, COSV60758990; called by muse, mutect2
- MAMLD1 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV53376359, COSV99475473; called by mutect2, varscan2
- MFN1 | c.760A>T p.R254* | Nonsense Mutation (SNP) | VAF 4/55 reads (7%) | catalogued as COSV54942616; called by muse, mutect2
- MGAM | c.5422C>T p.P1808S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1374422639, COSV72075896; called by muse, mutect2
- MKI67 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64077091; called by muse, mutect2, varscan2
- MMP7 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs371574667, COSV99497119; called by muse, mutect2, varscan2
- MN1 | c.2501A>G p.N834S | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV56562409; called by muse, mutect2, varscan2
- MPPED2 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV100813063; called by muse, mutect2, varscan2
- MPPED2 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1418654070, COSV100813064; called by muse, mutect2, varscan2
- MUC16 | c.19835C>A p.A6612D | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as rs780878506, COSV67495319; called by muse, mutect2, varscan2
- MUC16 | c.11375T>C p.M3792T | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.263); catalogued as COSV101200131, COSV67495325; called by muse, mutect2, varscan2
- MXRA5 | c.7891C>A p.L2631M | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54251261; called by muse, mutect2, varscan2
- NFATC2 | c.977G>T p.S326I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV65361369; called by muse, varscan2
- NLGN4X | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV52030516; called by muse, mutect2
- NPAP1 | c.2812G>T p.G938C | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV61511475; called by muse, mutect2, varscan2
- OPHN1 | c.914A>T p.Q305L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV62787132; called by muse, mutect2, varscan2
- OR2L8 | c.730C>A p.L244I | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); catalogued as COSV61728442; called by muse, mutect2, varscan2
- OR2M3 | c.122del p.G41Efs*90 | Frame Shift Del (DEL) | VAF 50/377 reads (13%) | catalogued as COSV101513419; called by mutect2, varscan2
- OR4M1 | c.595A>T p.M199L | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV60063664; called by muse, mutect2, varscan2
- OR56A3 | c.735T>A p.C245* | Nonsense Mutation (SNP) | VAF 66/233 reads (28%) | catalogued as COSV61570102; called by muse, mutect2, varscan2
- PCDH11X | c.2633C>A p.P878H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53505494; called by mutect2, varscan2
- PCDH15 | c.2840C>G p.T947R | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV57313814, COSV57397387; called by muse, mutect2, varscan2
- PCDHGA11 | c.2330G>T p.G777V | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV53910394; called by muse, mutect2, varscan2
- PLAAT4 | c.122A>G p.E41G | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV55373823; called by muse, mutect2, varscan2
- POLR3B | c.2571-2A>G p.X857_splice | Splice Site (SNP) | VAF 16/66 reads (24%) | catalogued as COSV57284867; called by muse, mutect2, varscan2
- PPL | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV62051142; called by muse, mutect2
- PROSER1 | c.1558G>T p.A520S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.036); catalogued as rs1232587550, COSV61488248, COSV61489732; called by muse, mutect2, varscan2
- PTPRZ1 | c.3217A>T p.N1073Y | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); catalogued as COSV66445911; called by muse, mutect2, varscan2
- RAB5B | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV64365287; called by mutect2, varscan2
- RANGRF | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1313732367, COSV56839485; called by muse, mutect2, varscan2
- RASD2 | c.250C>A p.R84S | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53352886, COSV53353647; called by muse, mutect2, varscan2
- RNF123 | c.3768C>G p.I1256M | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57540211; called by muse, mutect2
- RXFP1 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57048547, COSV57056968; called by muse, mutect2, varscan2
- SH2D1A | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV63578838, COSV63579879; called by muse, mutect2, varscan2
- SIGLEC6 | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58437646; called by muse, mutect2, varscan2
- SOX7 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100448926; called by muse, mutect2, varscan2
- SOX7 | c.1039G>T p.G347W | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100448930; called by muse, mutect2, varscan2
- SQSTM1 | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 12/62 reads (19%) | catalogued as COSV62435819; called by muse, mutect2, varscan2
- SS18 | c.694A>G p.M232V | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs1294143883, COSV52264048; called by muse, mutect2, varscan2
- SWT1 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs369688585; called by muse, mutect2, varscan2
- THSD7B | c.566C>A p.S189Y | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55739289; called by muse, mutect2, varscan2
- TLL2 | c.1871T>A p.I624N | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV63576119; called by muse, mutect2, varscan2
- TMTC2 | c.2177G>T p.R726L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58258896, COSV58284464; called by muse, mutect2, varscan2
- TNN | c.1612G>T p.V538L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV53436010; called by muse, mutect2, varscan2
- TPP1 | c.803G>C p.R268P | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs141920079, COSV54995249; called by muse, mutect2, varscan2
- TRIML1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs766822406, COSV60196898; called by muse, mutect2, varscan2
- TRPS1 | c.2368C>T p.R790C (on ENST00000220888 / NM_001330599.2; = p.R803C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/798 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV55250014; called by muse, mutect2
- TUBB4A | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs796738621, COSV51167425; called by muse, mutect2, varscan2
- U2SURP | c.2593A>T p.K865* | Nonsense Mutation (SNP) | VAF 6/26 reads (23%) | catalogued as COSV67533295; called by muse, mutect2, varscan2
- ULK4 | c.978C>A p.H326Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57224009; called by muse, mutect2, varscan2
- UROC1 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 14/120 reads (12%) | catalogued as COSV52039440; called by muse, mutect2, varscan2
- VRK2 | c.277A>G p.K93E | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as COSV60880704; called by muse, mutect2, varscan2
- ZCCHC12 | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs1282083496, COSV59573014; called by muse, mutect2, varscan2
- ZNF235 | c.1298G>A p.C433Y | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1371901848, COSV52158565; called by muse, mutect2, varscan2
- ZNF300 | c.550T>G p.F184V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs767809943, COSV51050589; called by muse, mutect2, varscan2
- ZNF331 | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.898); catalogued as COSV53480256; called by muse, mutect2, varscan2
- ZNF560 | c.472C>A p.L158M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV56871877; called by muse, mutect2, varscan2
- ZYX | c.599G>T p.W200L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.901); catalogued as rs150223874, COSV59556751; called by muse, mutect2, varscan2
- AATF | c.1512dup p.V505Sfs*3 | Frame Shift Ins (INS) | VAF 13/29 reads (45%) | called by mutect2, varscan2
- ADAMTSL1 | c.237+1del | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- ARL4A | c.69_97del p.V24Dfs*11 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | called by mutect2, pindel
- ATM | c.2251dup p.S751Ffs*14 | Frame Shift Ins (INS) | VAF 7/50 reads (14%) | called by mutect2, pindel
- CNTF | c.406dup p.R136Pfs*3 | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | called by pindel, varscan2
- SLITRK2 | c.919del p.M307* | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | called by mutect2, pindel, varscan2
- ACAN | c.414C>A p.G138= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV61369728; called by muse, mutect2, varscan2
- ACSF3 | c.855G>T p.P285= | Silent (SNP) | VAF 53/181 reads (29%) | catalogued as COSV58077880, COSV58081935; called by muse, mutect2, varscan2
- ADAMTS18 | c.1761C>A p.P587= | Silent (SNP) | VAF 62/174 reads (36%) | catalogued as COSV51422938, COSV51423295; called by muse, mutect2, varscan2
- AHNAK2 | c.5727G>T p.V1909= | Silent (SNP) | VAF 16/255 reads (6%) | catalogued as rs1446743591, COSV60931432; called by muse, mutect2
- ALK | c.1425T>A p.P475= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV66590184; called by muse, mutect2, varscan2
- CTBP1 | c.1167C>G p.A389= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs907249084, COSV52076608; called by muse, mutect2, varscan2
- DIDO1 | c.6144C>T p.S2048= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs760919841, COSV56634228; called by muse, mutect2, varscan2
- DLX1 | c.432C>T p.N144= | Silent (SNP) | VAF 64/238 reads (27%) | catalogued as COSV59395334; called by muse, mutect2, varscan2
- FLNA | c.3795T>C p.I1265= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV61052236; called by muse, mutect2, varscan2
- FMR1NB | c.339C>A p.G113= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV100789543, COSV63273011; called by muse, mutect2, varscan2
- FNTA | c.168G>T p.V56= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100172340; called by muse, mutect2
- GPC6 | c.612C>A p.P204= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV65538983; called by muse, mutect2, varscan2
- HCRTR2 | c.294G>A p.L98= | Silent (SNP) | VAF 45/187 reads (24%) | catalogued as COSV63799256; called by muse, mutect2, varscan2
- IGHE | c.702G>A p.S234= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs782705134; called by muse, mutect2, varscan2
- LTB4R | c.657C>A p.T219= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV51868181; called by muse, mutect2, varscan2
- MXRA5 | c.5338C>T p.L1780= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV54251280; called by muse, mutect2, varscan2
- NPAS3 | c.1929C>A p.A643= (on ENST00000356141 / NM_001164749.2; = p.A611= on NM_022123.3) | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV60863326; called by muse, mutect2, varscan2
- POM121L12 | c.726C>A p.P242= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV68692758; called by muse, mutect2, varscan2
- RXYLT1 | c.1068G>T p.V356= | Silent (SNP) | VAF 31/123 reads (25%) | catalogued as COSV54167513, COSV54170172; called by muse, mutect2, varscan2
- SOWAHD | c.726C>A p.A242= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100673104; called by muse, mutect2
- SYNDIG1 | c.309G>C p.G103= | Silent (SNP) | VAF 26/119 reads (22%) | catalogued as COSV65239941; called by muse, mutect2, varscan2
- SYTL5 | c.1458G>A p.L486= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV52905786; called by muse, mutect2, varscan2
- TEX11 | c.2031G>T p.L677= (on ENST00000344304; = p.L662= on NM_031276.3) | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV60230211; called by muse, mutect2, varscan2
- TMEM120B | c.450C>T p.V150= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV61186139; called by muse, mutect2, varscan2
- TTN | c.114C>T p.S38= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV60360140; called by muse, mutect2
- ZNF585A | c.246G>A p.K82= (on ENST00000292841 / NM_001288800.2; = p.K27= on NM_152655.3) | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV53067172; called by muse, mutect2, varscan2
- ZNF821 | c.6C>T p.S2= | Silent (SNP) | VAF 15/186 reads (8%) | catalogued as rs753231254, COSV57988376; called by muse, mutect2
- AL353804.4 | chrX:73825943 C>A | 5'Flank (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2
- CHCHD2P9 | n.153G>C | RNA (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- DDHD1 | chr14:53152585 A>T | 5'Flank (SNP) | VAF 12/74 reads (16%) | catalogued as COSV60362876; called by muse, mutect2, varscan2
- HKDC1 | c.-1A>T | 5'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100664304; called by muse, mutect2, varscan2
- RUSC1 | c.-86-346C>T | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as rs1404103860, COSV52742929; called by muse, mutect2, varscan2
- SSPOP | n.15324G>T | RNA (SNP) | VAF 7/46 reads (15%) | catalogued as COSV65137546; called by muse, mutect2, varscan2
